Somatic mutation profile of tumor specimen HCM-BROD-0615-C16-06A (aliquot HCM-BROD-0615-C16-06A-11D-A85K-36) from HCMI case HCM-BROD-0615-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.7 years (26,543 days).
Specimen HCM-BROD-0615-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8ee99c-a817-4129-bf72-826b9f069aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0615-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0615-C16-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6132e45-c002-4120-8d5b-2a32470a1060

The open-access MAF lists 161 somatic variants for this specimen: 119 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 37, Nonsense Mutation 7, Frame Shift Del 6, Intron 3, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 358/542 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504421, CM064328, CM139809, COSV55448438, COSV55452463; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1B10 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 71/843 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs757758746; called by muse, mutect2
- C5 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56331080; called by muse, mutect2, varscan2
- CDH1 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 245/507 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55737316; called by muse, mutect2, varscan2
- CFAP61 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 232/558 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs750210901, COSV55629755, COSV55645473; called by muse, mutect2, varscan2
- CHID1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 51/738 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs772974142, COSV60259317; called by muse, mutect2
- COL25A1 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 108/283 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); catalogued as COSV101211325; called by muse, mutect2, varscan2
- CRYGS | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 93/862 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100329920; called by muse, mutect2, varscan2
- DACH2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs749449951, COSV64174796; called by muse, mutect2, varscan2
- ELAVL2 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 109/508 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV56359092; called by muse, mutect2, varscan2
- EPB41L4A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs753031698; called by muse, mutect2, varscan2
- EQTN | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as rs748534572, COSV66219496; called by muse, mutect2, varscan2
- ERCC2 | c.569G>T p.C190F | Missense Mutation (SNP) | VAF 93/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330684188; called by muse, mutect2, varscan2
- FGFR4 | c.2389G>A p.G797R | Missense Mutation (SNP) | VAF 298/608 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.447); catalogued as rs200649056, COSV99448579; called by muse, mutect2, varscan2
- FLG | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 110/646 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs184361545, COSV64237804, COSV64243857; called by muse, mutect2, varscan2
- GRM3 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 264/701 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750079420, COSV64468260; called by muse, mutect2, varscan2
- H3C3 | c.331_332del p.C111Rfs*5 | Frame Shift Del (DEL) | VAF 440/1092 reads (40%) | catalogued as rs761955716; called by pindel, varscan2
- IL25 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 240/458 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199992202; called by muse, varscan2
- ITIH4 | c.2470G>A p.G824S | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as rs751486449; called by muse, mutect2, varscan2
- KCNB1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 295/673 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.903); catalogued as rs779379680, COSV65565968; called by muse, mutect2, varscan2
- LCP2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 126/469 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs779816058, COSV99252254; called by muse, mutect2, varscan2
- LCT | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 163/815 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51547667; called by muse, mutect2, varscan2
- LRRC7 | c.3053G>A p.R1018Q (on ENST00000651989 / NM_001370785.2; = p.R985Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.397); catalogued as rs535762389; called by muse, mutect2, varscan2
- MCHR2 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 117/592 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.6); catalogued as COSV56002939; called by muse, mutect2, varscan2
- NALCN | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51922474; called by muse, mutect2, varscan2
- NELL2 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 75/556 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs374154916; called by muse, mutect2, varscan2
- NOS1AP | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 111/631 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs918830650; called by muse, mutect2, varscan2
- NTRK1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 160/699 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs201035170, COSV100693573; called by muse, mutect2, varscan2
- OLR1 | c.260C>G p.A87G | Missense Mutation (SNP) | VAF 79/530 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.719); catalogued as COSV100376325; called by muse, mutect2, varscan2
- OR8J1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 53/694 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100274998, COSV100275285; called by muse, mutect2
- ORAI2 | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 341/3246 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.96); catalogued as COSV62689149; called by muse, mutect2, varscan2
- PCDHGB4 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 107/462 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1470979893; called by muse, mutect2, varscan2
- PPP1R2C | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); catalogued as rs1277924532; called by muse, mutect2, varscan2
- PRDM9 | c.1553T>A p.I518N | Missense Mutation (SNP) | VAF 72/466 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV57008341; called by muse, mutect2, varscan2
- PTPRQ | c.5064C>A p.N1688K (on ENST00000616559; = p.N1646K on NM_001145026.2) | Missense Mutation (SNP) | VAF 142/356 reads (40%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.734); catalogued as COSV57053967; called by muse, mutect2, varscan2
- RNF144B | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 260/421 reads (62%) | catalogued as rs1391494740; called by muse, mutect2, varscan2
- RNF17 | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55037445; called by muse, mutect2, varscan2
- RPL11 | c.101G>C p.R34P (on ENST00000374550 / NM_001199802.1; = p.R35P on NM_000975.5) | Missense Mutation (SNP) | VAF 166/467 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV100999661; called by muse, mutect2, varscan2
- SALL1 | c.3968C>T p.T1323M | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1460897474; called by muse, mutect2, varscan2
- SH3KBP1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 177/657 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1432635413, COSV65645947; called by muse, mutect2, varscan2
- SHC2 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs577660537; called by muse, varscan2
- SIGLEC11 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767835963, COSV101357106; called by muse, mutect2, varscan2
- SLC13A2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 265/798 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1390950797; called by muse, mutect2, varscan2
- SLIT3 | c.1541C>G p.T514R | Missense Mutation (SNP) | VAF 212/490 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs771738292; called by muse, mutect2, varscan2
- TAS1R2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 103/554 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756284683; called by muse, mutect2, varscan2
- TIE1 | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 107/528 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199739316; called by muse, mutect2, varscan2
- TLR5 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 84/612 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs868711690, COSV60560579; called by muse, mutect2, varscan2
- TMEM132D | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 78/666 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67161516; called by muse, mutect2, varscan2
- TP53BP2 | c.570G>C p.E190D (on ENST00000343537 / NM_001031685.3; = p.E61D on NM_005426.2) | Missense Mutation (SNP) | VAF 89/635 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59071740; called by muse, mutect2, varscan2
- TPSG1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 342/756 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs760619425; called by muse, mutect2, varscan2
- TRIP10 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57575464; called by muse, mutect2, varscan2
- TSGA10IP | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 114/867 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1047974664; called by muse, mutect2, varscan2
- USP29 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.917); catalogued as COSV54147112; called by muse, mutect2, varscan2
- A2ML1 | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.15652G>C p.G5218R | Missense Mutation (SNP) | VAF 102/569 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKLE2 | c.2396C>G p.A799G | Missense Mutation (SNP) | VAF 117/948 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP13A4 | c.1322C>A p.A441E | Missense Mutation (SNP) | VAF 234/674 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BNIP3 | c.244T>A p.S82T | Missense Mutation (SNP) | VAF 57/546 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- C4orf54 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 60/390 reads (15%) | called by muse, mutect2, varscan2
- CCDC168 | c.10163C>G p.T3388R | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDKL5 | c.1639A>T p.R547* | Nonsense Mutation (SNP) | VAF 87/559 reads (16%) | called by muse, mutect2, varscan2
- CEP170B | c.2299C>A p.Q767K (on ENST00000453495; = p.Q696K on NM_015005.3) | Missense Mutation (SNP) | VAF 116/1519 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.209); called by muse, mutect2
- CEP85L | c.1434A>T p.E478D | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP61 | c.2842A>G p.K948E | Missense Mutation (SNP) | VAF 48/575 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- CFAP74 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 192/608 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CHST9 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 206/482 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CREB5 | c.587T>C p.M196T (on ENST00000357727 / NM_182898.4; = p.M189T on NM_004904.3) | Missense Mutation (SNP) | VAF 64/552 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CRH | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 269/610 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DACH2 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 162/498 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- DEUP1 | c.1076dup p.H359Qfs*2 | Frame Shift Ins (INS) | VAF 60/543 reads (11%) | called by mutect2, pindel, varscan2
- EEF2 | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 134/655 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHD1 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 300/946 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYA1 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM120A | c.1506+1del | Frame Shift Del (DEL) | VAF 195/397 reads (49%) | called by mutect2, pindel, varscan2
- FER1L5 | c.1186C>A p.Q396K (on ENST00000623019; = p.Q413K on NM_001293083.2) | Missense Mutation (SNP) | VAF 126/640 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FER1L5 | c.1187A>C p.Q396P (on ENST00000623019; = p.Q413P on NM_001293083.2) | Missense Mutation (SNP) | VAF 126/641 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FIGLA | c.39_43dup p.P15Rfs*66 | Frame Shift Ins (INS) | VAF 174/840 reads (21%) | called by mutect2, varscan2
- FPGT-TNNI3K | c.999G>C p.L333F | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- GABBR1 | c.2156G>C p.G719A | Missense Mutation (SNP) | VAF 358/1599 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GAS7 | c.524C>A p.T175K (on ENST00000432992 / NM_201433.2; = p.T35K on NM_003644.3) | Missense Mutation (SNP) | VAF 291/450 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GIMAP2 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNB4 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 52/739 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPM6A | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 112/606 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD3 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 222/682 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, varscan2
- HYDIN | c.2555T>A p.I852N | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- KDM4D | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 127/750 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2D | c.4357C>T p.H1453Y | Missense Mutation (SNP) | VAF 127/736 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRA6 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 128/756 reads (17%) | called by muse, varscan2
- MAPKBP1 | c.2203G>C p.E735Q (on ENST00000456763 / NM_001128608.2; = p.E729Q on NM_014994.3) | Missense Mutation (SNP) | VAF 83/737 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MEPCE | c.932A>T p.D311V | Missense Mutation (SNP) | VAF 154/4130 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.916); called by muse, mutect2
- NALCN | c.4342del p.E1448Rfs*15 | Frame Shift Del (DEL) | VAF 32/251 reads (13%) | called by mutect2, pindel, varscan2
- NELL1 | c.1055G>C p.S352T | Missense Mutation (SNP) | VAF 205/488 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPR1 | c.1965C>G p.I655M | Missense Mutation (SNP) | VAF 71/536 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NRK | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 76/494 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OR2T6 | c.853T>G p.L285V | Missense Mutation (SNP) | VAF 103/593 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OR5D3P | c.153T>A p.N51K | Missense Mutation (SNP) | VAF 134/504 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR5H15 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 170/479 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR5K1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 28/804 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PAPPA2 | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 113/557 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.6086A>G p.H2029R | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PKP3 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 202/841 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POM121 | c.1283A>T p.K428M (on ENST00000434423; = p.K163M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/679 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PXDNL | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 203/547 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RIMS4 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 116/965 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- RP1 | c.2566A>T p.K856* | Nonsense Mutation (SNP) | VAF 165/628 reads (26%) | called by muse, mutect2, varscan2
- SCN8A | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 54/366 reads (15%) | called by muse, mutect2, varscan2
- SEMA3D | c.991C>A p.L331I | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF4 | c.1041_1089del p.K348Afs*45 | Frame Shift Del (DEL) | VAF 138/690 reads (20%) | called by mutect2, pindel
- TAF4 | c.139_172del p.T47Sfs*6 | Frame Shift Del (DEL) | VAF 229/784 reads (29%) | called by mutect2, pindel, varscan2
- THSD7A | c.3752G>T p.C1251F | Missense Mutation (SNP) | VAF 337/817 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM74 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 121/757 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TMPRSS11D | c.933G>A p.W311* | Nonsense Mutation (SNP) | VAF 234/352 reads (66%) | called by muse, mutect2, varscan2
- TP53 | c.929_932del p.N310Tfs*34 | Frame Shift Del (DEL) | VAF 335/486 reads (69%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.846G>T p.L282F (on ENST00000343537 / NM_001031685.3; = p.L153F on NM_005426.2) | Missense Mutation (SNP) | VAF 63/467 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPH2 | c.980T>A p.L327H | Missense Mutation (SNP) | VAF 68/491 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- TUT1 | c.131T>A p.V44E | Missense Mutation (SNP) | VAF 98/669 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUT7 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 53/477 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC13C | c.4388T>A p.V1463D | Missense Mutation (SNP) | VAF 57/571 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- WDR81 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 163/926 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AKAP17A | c.1539C>T p.N513= | Silent (SNP) | VAF 152/1092 reads (14%) | catalogued as rs202130845, COSV100001907; called by muse, mutect2, varscan2
- AMDHD1 | c.63C>G p.R21= | Silent (SNP) | VAF 116/924 reads (13%) | called by muse, mutect2, varscan2
- ATP10D | c.1032G>A p.L344= | Silent (SNP) | VAF 268/431 reads (62%) | catalogued as rs147184971; called by muse, mutect2, varscan2
- CAD | c.3078G>A p.A1026= | Silent (SNP) | VAF 50/1134 reads (4%) | catalogued as rs200398980; called by muse, mutect2
- CCNT2 | c.1035A>G p.L345= | Silent (SNP) | VAF 392/964 reads (41%) | catalogued as rs1196027808; called by muse, mutect2, varscan2
- CDR2 | c.756C>T p.A252= | Silent (SNP) | VAF 127/780 reads (16%) | catalogued as rs763408452; called by muse, mutect2, varscan2
- COL22A1 | c.522C>T p.A174= | Silent (SNP) | VAF 435/1090 reads (40%) | catalogued as rs775573229; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 168/654 reads (26%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DCSTAMP | c.576A>G p.E192= | Silent (SNP) | VAF 288/957 reads (30%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2472C>A p.A824= | Silent (SNP) | VAF 244/708 reads (34%) | called by muse, mutect2, varscan2
- FSTL3 | c.120C>T p.L40= | Silent (SNP) | VAF 102/500 reads (20%) | called by muse, mutect2, varscan2
- IL17RD | c.1914C>T p.D638= | Silent (SNP) | VAF 404/612 reads (66%) | catalogued as rs755627496, COSV56345088; called by muse, mutect2, varscan2
- ITIH5 | c.1149C>T p.L383= | Silent (SNP) | VAF 75/520 reads (14%) | catalogued as rs138140357; called by muse, mutect2, varscan2
- KATNIP | c.1755T>C p.I585= | Silent (SNP) | VAF 182/430 reads (42%) | called by muse, mutect2, varscan2
- KCNQ4 | c.2040C>T p.S680= | Silent (SNP) | VAF 218/574 reads (38%) | catalogued as rs367871533, COSV100714348; called by muse, varscan2
- LY9 | c.1068C>T p.I356= | Silent (SNP) | VAF 53/410 reads (13%) | called by muse, mutect2, varscan2
- NKX2-8 | c.210G>A p.P70= | Silent (SNP) | VAF 119/630 reads (19%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 344/891 reads (39%) | catalogued as rs1554143388, COSV65324575; called by muse, varscan2
- PGBD1 | c.1738C>T p.L580= | Silent (SNP) | VAF 149/977 reads (15%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1944G>A p.V648= | Silent (SNP) | VAF 88/500 reads (18%) | catalogued as rs1190008232; called by muse, mutect2, varscan2
- PXDNL | c.2304C>T p.G768= | Silent (SNP) | VAF 128/906 reads (14%) | called by muse, mutect2, varscan2
- PYGL | c.51C>A p.R17= | Silent (SNP) | VAF 103/479 reads (22%) | called by muse, mutect2, varscan2
- RBMXL2 | c.564C>T p.D188= | Silent (SNP) | VAF 131/756 reads (17%) | catalogued as rs1395537265; called by muse, mutect2, varscan2
- SEMA5A | c.1587C>T p.I529= | Silent (SNP) | VAF 69/753 reads (9%) | catalogued as COSV66806427; called by muse, mutect2
- SEMA6D | c.2430G>A p.P810= (on ENST00000316364 / NM_153618.2; = p.P748= on NM_020858.2) | Silent (SNP) | VAF 375/774 reads (48%) | catalogued as rs144939945; called by muse, mutect2, varscan2
- SLC18A3 | c.273C>T p.S91= | Silent (SNP) | VAF 481/794 reads (61%) | called by muse, mutect2, varscan2
- SLC33A1 | c.1215A>T p.G405= | Silent (SNP) | VAF 65/748 reads (9%) | catalogued as rs201719045; called by muse, mutect2
- SLC5A8 | c.1209G>A p.A403= | Silent (SNP) | VAF 492/796 reads (62%) | catalogued as rs780465977; called by muse, varscan2
- SLC6A2 | c.1344C>G p.G448= | Silent (SNP) | VAF 144/651 reads (22%) | catalogued as COSV99574813; called by muse, mutect2, varscan2
- SYNE1 | c.11055A>G p.R3685= (on ENST00000367255 / NM_182961.4; = p.R3670= on NM_033071.3) | Silent (SNP) | VAF 82/419 reads (20%) | called by muse, mutect2, varscan2
- THEGL | c.489G>T p.L163= | Silent (SNP) | VAF 72/472 reads (15%) | called by muse, mutect2, varscan2
- TLR5 | c.135C>A p.L45= | Silent (SNP) | VAF 95/679 reads (14%) | called by muse, mutect2, varscan2
- TP63 | c.351G>A p.L117= | Silent (SNP) | VAF 292/791 reads (37%) | called by muse, mutect2, varscan2
- TRIM10 | c.1053C>A p.A351= | Silent (SNP) | VAF 244/2708 reads (9%) | called by muse, mutect2
- TRPC3 | c.531C>T p.D177= (on ENST00000379645 / NM_001366479.2; = p.D104= on NM_003305.2) | Silent (SNP) | VAF 176/454 reads (39%) | catalogued as rs200580955; called by muse, mutect2, varscan2
- VSX1 | c.183G>A p.A61= | Silent (SNP) | VAF 443/1133 reads (39%) | catalogued as rs1394252540; called by muse, varscan2
- ZIC4 | c.249G>A p.A83= | Silent (SNP) | VAF 322/965 reads (33%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58841954 C>T | 5'Flank (SNP) | VAF 65/592 reads (11%) | catalogued as rs557127211; called by muse, mutect2, varscan2
- FER1L5 | c.3822+21G>T | Intron (SNP) | VAF 73/452 reads (16%) | called by muse, mutect2, varscan2
- MAFB | c.*781C>T | 3'UTR (SNP) | VAF 205/795 reads (26%) | catalogued as COSV64826355; called by muse, mutect2, varscan2
- MARCHF8 | c.242+718G>T | Intron (SNP) | VAF 104/571 reads (18%) | catalogued as COSV60570472; called by muse, mutect2, varscan2
- SLC6A15 | c.756+76G>A | Intron (SNP) | VAF 44/462 reads (10%) | catalogued as rs1353138197, COSV99880261; called by muse, mutect2, varscan2
